Somatic mutation profile of tumor specimen TARGET-40-NAAGJU-01A (aliquot TARGET-40-NAAGJU-01A-01D) from TARGET case TARGET-40-NAAGJU, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 12.8 years (4,671 days).
Specimen TARGET-40-NAAGJU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12043806-c9a8-4c68-96e4-3ab74928a6eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAGJU-10A (Blood Derived Normal), aliquot TARGET-40-NAAGJU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f65e457-31a9-4f53-a1f9-a3e1b8053384

The open-access MAF lists 16 somatic variants for this specimen: 14 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Splice Region 1, Nonsense Mutation 1, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARPP21 | c.985C>T p.Q329* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV99493814; called by muse, mutect2, varscan2
- ATP2B4 | c.1979C>T p.T660I | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV58179322; called by muse, mutect2, varscan2
- BTNL8 | c.800C>T p.A267V (on ENST00000340184 / NM_001040462.3; = p.G310= on NM_024850.2) | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.134); catalogued as rs755335177, COSV99180400; called by muse, mutect2, varscan2
- CCNE1 | c.743C>G p.S248C | Missense Mutation (SNP) | VAF 59/516 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV99388679; called by muse, mutect2, varscan2
- COL11A2 | c.4538G>A p.R1513Q (on ENST00000341947 / NM_080680.3; = p.R1406Q on NM_080679.2) | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as rs371674362; called by muse, mutect2, varscan2
- COL4A1 | c.3419C>T p.T1140I | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.947); catalogued as COSV65422450; called by muse, mutect2
- CD1B | c.225C>A p.N75K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- CLUL1 | c.984C>A p.H328Q | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.206); called by muse, mutect2
- NACAD | c.831G>T p.E277D | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.255); called by muse, mutect2
- PKD2L1 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- PTPDC1 | c.966G>C p.K322N (on ENST00000375360 / NM_177995.3; = p.K374N on NM_152422.4) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- SLX4 | c.1043G>A p.S348N | Missense Mutation (SNP) | VAF 35/262 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- UGGT1 | c.3456C>A p.G1152= | Splice Region (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2
- ZNF264 | c.1306T>C p.F436L | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SPINK5 | c.3150C>T p.S1050= | Silent (SNP) | VAF 79/147 reads (54%) | called by muse, mutect2, varscan2
- WASHC2A | c.-38G>C | 5'UTR (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2
